Somatic mutation profile of tumor specimen TCGA-BP-4964-01A (aliquot TCGA-BP-4964-01A-01D-1462-08) from TCGA case TCGA-BP-4964, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.0 years (20,084 days).
Specimen TCGA-BP-4964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8dd42b8-ef6b-4adc-97ca-60f9c386cee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4964-11A (Solid Tissue Normal), aliquot TCGA-BP-4964-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dca68d7-4d20-4bad-8e7a-0a92d69115f2

The open-access MAF lists 91 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 19, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 2, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 12/109 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- VHL | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 4/8 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs869025621, CM130353, CM130970, CM941365, COSV56545109, COSV56549825, COSV56558459; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGO2 | c.2169+1G>A p.X723_splice | Splice Site (SNP) | VAF 40/137 reads (29%) | catalogued as COSV55047291; called by muse, mutect2, varscan2
- AGO2 | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55047303; called by muse, mutect2, varscan2
- ARHGAP30 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV63512630; called by muse, mutect2, varscan2
- ARPP21 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51797315; called by muse, mutect2
- ATM | c.9010A>G p.K3004E | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1555151737, COSV53742856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD7 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67158770; called by muse, mutect2, varscan2
- CCDC50 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 107/389 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as rs376944531, COSV66667521; called by muse, mutect2, varscan2
- CDIN1 | c.463G>T p.D155Y (on ENST00000437989; = p.D57Y on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV57711260; called by muse, mutect2, varscan2
- CHN1 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV69296384; called by muse, mutect2
- CLSPN | c.75T>G p.D25E | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV52050724; called by muse, mutect2, varscan2
- CNTNAP4 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV56678835, COSV56692547; called by muse, mutect2, varscan2
- DENND4A | c.5127G>A p.M1709I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.53); catalogued as COSV71265719; called by muse, mutect2, varscan2
- EPHX2 | c.370A>T p.N124Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66844757; called by muse, mutect2, varscan2
- FRMD4A | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV62265997; called by muse, mutect2, varscan2
- GRM5 | c.332A>C p.E111A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV59603919, COSV59625716; called by muse, mutect2, varscan2
- HUS1 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51839409; called by muse, mutect2, varscan2
- INCENP | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53915452; called by muse, mutect2, varscan2
- INCENP | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs772664621, COSV53915489; called by muse, mutect2, varscan2
- ITIH5 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV53663837; called by muse, mutect2
- KIAA0319 | c.2092C>A p.Q698K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV65497923; called by muse, mutect2, varscan2
- KRTAP10-5 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV59961300; called by muse, mutect2, varscan2
- LMLN | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs370291786; called by muse, mutect2, varscan2
- LOXL2 | c.1727A>C p.E576A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66691389; called by muse, mutect2, varscan2
- LRIG2 | c.2755T>C p.C919R | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs775541563, COSV63162003; called by muse, mutect2
- LRP1 | c.8066C>A p.P2689Q | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV54510508; called by muse, mutect2
- ME3 | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV62772283; called by muse, mutect2
- MRPL1 | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59674557; called by muse, mutect2
- MSH4 | c.1451C>A p.T484N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV54202400; called by muse, mutect2
- MUC16 | c.20639T>A p.M6880K | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV67464019; called by muse, mutect2, varscan2
- MYNN | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.879); catalogued as COSV62991260; called by muse, mutect2
- NDUFS5 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV65892337; called by muse, mutect2, varscan2
- NSF | c.1227C>G p.I409M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99834015; called by mutect2, varscan2
- OTUD3 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64295793; called by muse, mutect2, varscan2
- PAK1 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53696299; called by muse, mutect2
- PCNT | c.7091G>C p.G2364A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as COSV64027870; called by muse, mutect2, varscan2
- PLEKHH1 | c.1694C>A p.S565* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV61283176; called by muse, mutect2, varscan2
- PLXNA4 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs199571283, COSV58102572; called by muse, mutect2
- PPP2CA | c.733A>T p.M245L | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV51538172; called by muse, mutect2
- PTGS2 | c.1185C>A p.Y395* | Nonsense Mutation (SNP) | VAF 17/192 reads (9%) | catalogued as COSV66569213; called by muse, mutect2
- PWWP3B | c.1388G>T p.S463I | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.387); catalogued as COSV61799595; called by muse, mutect2, varscan2
- RAB40A | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58491128; called by muse, mutect2
- RALGPS2 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61336995; called by muse, mutect2
- RANBP3L | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 48/172 reads (28%) | catalogued as COSV56955487; called by muse, mutect2, varscan2
- SEC14L2 | c.533T>A p.F178Y | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV57241037; called by muse, mutect2, varscan2
- SLC27A6 | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476601907, COSV52482763; called by muse, mutect2, varscan2
- SLC9A5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762466239, COSV55361960; called by muse, mutect2
- SPECC1 | c.2546T>A p.L849Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54957691; called by muse, mutect2, varscan2
- SVEP1 | c.9247del p.E3083Kfs*3 | Frame Shift Del (DEL) | VAF 89/286 reads (31%) | catalogued as COSV52836686; called by mutect2, pindel, varscan2
- TAS1R3 | c.1339A>G p.S447G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV59563299; called by muse, mutect2, varscan2
- TMEM140 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as rs893342236, COSV51966164; called by muse, mutect2, varscan2
- TMEM213 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs375761457; called by muse, mutect2, varscan2
- TSSK4 | c.422G>T p.S141I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV55303139; called by muse, mutect2, varscan2
- TTN | c.27934G>C p.E9312Q (on ENST00000591111; = p.E8385Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | PolyPhen probably damaging (0.964); catalogued as COSV60005669, COSV60041014; called by muse, mutect2
- UTP6 | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV55573265; called by muse, mutect2, varscan2
- WNT5B | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60197923; called by mutect2, varscan2
- ZNF326 | c.808T>G p.S270A | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as COSV61035212; called by muse, mutect2, varscan2
- ZNF341 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV61008383; called by muse, mutect2
- ZNF572 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV60001895; called by muse, mutect2, varscan2
- ZNF574 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.746); catalogued as COSV55903210; called by muse, mutect2, varscan2
- ZNF721 | c.1266A>C p.E422D (on ENST00000338977; = p.E434D on NM_133474.4) | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.255); catalogued as COSV59092254; called by muse, mutect2, varscan2
- ZNF79 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV61070902; called by muse, mutect2, varscan2
- ZNF878 | c.976T>A p.F326I | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV72155993, COSV72156108; called by muse, mutect2, varscan2
- ANKIB1 | c.1005_1015del p.I335Mfs*6 | Frame Shift Del (DEL) | VAF 117/471 reads (25%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4037del p.Q1346Rfs*38 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, pindel, varscan2
- PIGV | c.705del p.F235Lfs*3 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | called by mutect2, pindel, varscan2
- PSMA3 | c.396dup p.G133Wfs*13 | Frame Shift Ins (INS) | VAF 43/158 reads (27%) | called by mutect2, pindel, varscan2
- SCN1A | c.4860del p.A1622Pfs*3 (on ENST00000303395 / NM_001202435.3; = p.A1611Pfs*3 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- WAPL | c.1341_1352del p.N447_I450del | In Frame Del (DEL) | VAF 19/154 reads (12%) | called by mutect2, pindel, varscan2
- AMOTL1 | c.1323C>G p.A441= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV58566460; called by mutect2, varscan2
- AVIL | c.657G>A p.L219= | Silent (SNP) | VAF 16/195 reads (8%) | catalogued as COSV57681733; called by muse, mutect2
- CUL3 | c.2256A>G p.E752= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV52364557; called by muse, mutect2
- DCAF8L1 | c.1185C>T p.C395= | Silent (SNP) | VAF 19/219 reads (9%) | catalogued as rs371674204, COSV101491434, COSV71595269; called by muse, mutect2
- F2RL1 | c.279C>T p.N93= | Silent (SNP) | VAF 40/323 reads (12%) | catalogued as rs760708378, COSV56995701; called by muse, mutect2, varscan2
- HECTD3 | c.276C>G p.A92= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV55800172; called by mutect2, varscan2
- KMT2D | c.3624C>T p.I1208= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs755572302, COSV56437759, COSV56471303; called by muse, mutect2, varscan2
- MSL2 | c.63C>T p.D21= | Silent (SNP) | VAF 86/334 reads (26%) | catalogued as rs760598672, COSV59442516; called by muse, mutect2, varscan2
- NOS1 | c.1728C>G p.L576= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV57611861, COSV57618438; called by muse, mutect2, varscan2
- NUGGC | c.27C>T p.G9= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV58434544; called by muse, mutect2
- NYAP1 | c.486G>A p.Q162= | Silent (SNP) | VAF 102/341 reads (30%) | catalogued as COSV55718754; called by muse, mutect2, varscan2
- PARVA | c.471G>T p.L157= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs754964245, COSV58514323; called by muse, mutect2, varscan2
- SEMG1 | c.1200T>C p.G400= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV54872737; called by muse, mutect2, varscan2
- SKIL | c.102G>A p.T34= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs778454510, COSV52059703; called by muse, mutect2, varscan2
- UNC79 | c.5166C>T p.D1722= (on ENST00000393151 / NM_001346218.2; = p.D1545= on NM_020818.5) | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as rs773882042, COSV56386758; called by muse, mutect2, varscan2
- ZNF322 | c.303T>C p.C101= | Silent (SNP) | VAF 139/476 reads (29%) | catalogued as rs1242060262, COSV70651955; called by muse, mutect2, varscan2
- ZNF79 | c.1080C>T p.P360= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100688211, COSV61070893; called by muse, mutect2, varscan2
- ZZEF1 | c.7560G>A p.R2520= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV67557350; called by muse, mutect2, varscan2
- ZZEF1 | c.1593T>C p.T531= | Silent (SNP) | VAF 64/211 reads (30%) | catalogued as COSV67557354; called by muse, mutect2, varscan2
- UVSSA | c.*9373C>T | 3'UTR (SNP) | VAF 27/224 reads (12%) | catalogued as rs552730277, COSV61348651; called by muse, varscan2
- XIST | n.9448T>C | RNA (SNP) | VAF 60/205 reads (29%) | called by muse, mutect2, varscan2
